MMRF case MMRF_1668 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ca7436ce-324c-492a-99b1-0b478a37a028

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Dead; Days to death: 308 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.1 years (23,063 days); ISS stage: I; Days to last known disease status: 308 days; Days to last follow up: 308 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 142 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 142 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 142 days.
   Treatment given: Therapeutic agents: Carfilzomib + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 142 days; Days to treatment end: 202 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 143 days; Days to treatment end: 202 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 209 days; Days to treatment end: 251 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Third line of therapy; Days to treatment start: 251 days; Days to treatment end: 251 days.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 1, day 308.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1: M Protein 2.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 176 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.18 mg/dL; Immunoglobulin G 30.3 g/L; Immunoglobulin A 0.286 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 0.3 µg/mL; Lactate Dehydrogenase 5.38 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 302 µmol/L; Blood Urea Nitrogen 18.9 mmol/L; Calcium 2.73 mmol/L; Albumin 40 g/L; Total Protein 9.7 g/dL; Glucose 7.65 mmol/L.
- Day 77 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 25.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 4.92 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.278 g/L; Lactate Dehydrogenase 4.22 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 375 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 7.4 g/dL; Glucose 6 mmol/L.
- Day 170 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 55.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.23 mg/dL; Immunoglobulin G 6.49 g/L; Immunoglobulin A 0.636 g/L; Immunoglobulin M 0.304 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 4.77 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 726 µmol/L; Blood Urea Nitrogen 43.6 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 7.5 g/dL; Glucose 6.27 mmol/L.
- Day 273: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 45.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 2.6 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 4.59 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 60 ×10⁹/L; Creatinine 443 µmol/L; Blood Urea Nitrogen 14.6 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 6 g/dL; Glucose 10.1 mmol/L.

Other clinical attributes
- Day 1: Weight: 100 kg; Height: 174 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Bladder Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1668_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1668_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
